Somatic mutation profile of tumor specimen C3L-05892-54 (aliquot CPT0344570002) from CPTAC case C3L-05892, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 25.3 years (9,249 days).
Specimen C3L-05892-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35b24497-f6ab-41a6-93ed-1de980abcc7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05892-50 (Buccal Cell Normal), aliquot CPT0344540003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76a48682-36fd-47a9-ac70-f313e552e3d0

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCHE | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs778566503, COSV52262369, COSV52263017; called by muse, mutect2, varscan2
- SLC12A7 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs1561079212; called by muse, mutect2
- SORCS1 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 39/173 reads (23%) | catalogued as COSV99551464; called by muse, mutect2, varscan2
- DYTN | c.602A>G p.Q201R | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAP4K4 | c.2517+1098G>A | Intron (SNP) | VAF 14/60 reads (23%) | catalogued as rs1443683518; called by muse, varscan2
